Gene-level copy-number profile of tumor specimen ALCH-B4SP-TTP1-A from ALCHEMIST case ALCH-B4SP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.7 years (18,519 days).
Specimen ALCH-B4SP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file db6dcb3c-62b5-448a-8dbc-b2615dc6ed5f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4SP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/7583d097-1bc8-463c-a4fe-df9bd022754a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 133; copy number 1: 5,312; copy number 2: 53,207; copy number 3: 166; copy number 4: 12; copy number 5: 14; copy number 7: 1; copy number 8: 2; copy number 9: 2; copy number 10: 4; copy number 12: 1; copy number 13: 28; copy number 18: 1; copy number 52: 1; copy number 58: 2; copy number 60: 1.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,082,688–110,113,947, 2 genes: LINC01397, UBL4B.
- chr1:119,000,344–119,001,405, 2 genes: AL139420.1, AL139420.2.
- chr1:202,096,759–202,096,978, 1 gene: CRIP1P3.
- chr2:11,584,773–11,585,047, 1 gene (within-gene range 0–2): RN7SL674P.
- chr2:25,227,855–25,375,845, 3 genes: DNMT3A, MIR1301, ARNILA.
- chr2:44,921,077–44,968,762, 12 genes: LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:131,821,987–131,832,031, 2 genes: AC103564.3, AC103564.1.
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr3:53,156,009–53,256,052, 2 genes: PRKCD, TKT.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr7:44,217,150–44,334,577, 1 gene: CAMK2B.
- chr7:128,912,732–128,950,038, 2 genes: AC025594.1, IRF5.
- chr7:129,774,692–129,785,185, 3 genes: MIR96, MIR183, AC084864.1.
- chr8:101,686,547–101,689,093, 1 gene (within-gene range 0–2): AP000426.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr10:8,045,378–8,075,198, 3 genes: GATA3, GATA3-AS1, AL390294.1.
- chr10:11,849,608–11,894,700, 1 gene (within-gene range 0–2): PROSER2-AS1.
- chr11:494,512–507,300, 1 gene: RNH1.
- chr11:565,660–568,457, 2 genes: MIR210HG, MIR210.
- chr11:2,129,112–2,158,391, 3 genes (within-gene range 0–2): IGF2, AC132217.2, AC132217.1.
- chr11:2,134,134–2,148,666, 2 genes (within-gene range 0–2): MIR483, IGF2-AS.
- chr11:32,435,738–32,440,383, 6 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–2): OTUB1.
- chr12:121,626,550–121,642,677, 1 gene: ORAI1.
- chr14:103,100,144–103,123,007, 2 genes: EXOC3L4, LINC00677.
- chr15:21,298,233–21,325,241, 2 genes: AC068446.2, RNU6-1235P.
- chr15:25,178,738–25,189,495, 7 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11.
- chr15:85,272,527–85,272,974, 1 gene (within-gene range 0–2): AC044860.3.
- chr17:16,415,571–16,492,193, 8 genes (within-gene range 0–2): TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:62,679,403–62,684,010, 2 genes (within-gene range 0–2): AC080038.3, RNU6-446P.
- chr17:78,107,397–78,142,968, 2 genes (within-gene range 0–2): TMC6, TMC8.
- chr21:36,698,773–36,749,917, 2 genes: AP000697.1, SIM2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.
- chr22:19,714,503–19,724,772, 3 genes: SEPTIN5, AC000093.1, GP1BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,984,522, 1 gene, copy number 9 (within-gene range 1–9): MRPL23.
- chr15:21,293,653–21,295,201, 1 gene, copy number 5: AC068446.1.
- chr15:21,405,401–22,095,857, 37 genes, copy number 5–52 (within-gene range 2–52): POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2.
- chr16:1,833,986–1,890,434, 4 genes, copy number 5 (within-gene range 2–5): MEIOB, AL031722.1, LINC00254, LINC02124.
- chr21:43,092,956–43,172,805, 6 genes, copy number 7–58: U2AF1, AP001631.2, MRPL51P2, FRGCA, AP001631.1, CRYAA.
- chr21:43,446,601–43,479,534, 3 genes, copy number 10–60: LINC00319, LINC00313, AP001048.1.
- chr22:21,300,990–21,371,945, 5 genes, copy number 5–10 (within-gene range 2–10): FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1.

Autosomal genes at a single copy (total copy number 1): 2,501. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
